Gene-level copy-number profile of tumor specimen TCGA-50-5935-01A from TCGA case TCGA-50-5935, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 86.5 years (31,610 days).
Specimen TCGA-50-5935-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.640c682c-2f19-4307-853f-1ea70c3f55a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-5935-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2d1388f8-b6df-4c83-8420-ca52c1a07f2d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 564; copy number 2: 13,657; copy number 3: 25,645; copy number 4: 14,148; copy number 5: 2,919; copy number 6: 8; copy number 7: 26; copy number 8: 2,803; copy number 12: 18; copy number 14: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-5935-01A-11D-1752-01): tumor purity 0.39, ploidy 5.81, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,875 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 8 (broad region; genes not listed).
- chr14:34,416,687–44,507,283, 149 genes, copy number 8–14 (broad region; genes not listed).
- chr14:52,430,596–57,982,194, 99 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr14:57,999,735–58,298,139, 1 gene, copy number 7 (within-gene range 4–12): ARMH4.
- chr14:58,141,279–58,648,321, 21 genes, copy number 7–12: UBA52P3, RN7SL598P, AL121579.1, ACTR10, PSMA3, AL132989.1, PSMA3-AS1, HMGB1P14, LINC00216, RNU6-341P, ARID4A, AL139021.2, TOMM20L, AL139021.1, TIMM9, KIAA0586, Y_RNA, HSBP1P1, HNRNPCP1, RPL9P5, DACT1.
- chr14:58,794,654–58,795,029, 1 gene, copy number 12: AL049873.1.

Autosomal genes at a single copy (total copy number 1): 564. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
